Gene-level copy-number profile of tumor specimen TCGA-L5-A8NW-01A from TCGA case TCGA-L5-A8NW, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: GX; Age at diagnosis: 55.3 years (20,194 days).
Specimen TCGA-L5-A8NW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.904da374-db86-42af-a3ae-1fe10add5c0d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A8NW-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d9a13abd-1187-4a7a-993b-6ba4b59cb2c2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 89; copy number 1: 6,256; copy number 2: 38,850; copy number 3: 9,209; copy number 4: 1,554; copy number 5: 3,308; copy number 6: 431; copy number 7: 72; copy number 8: 31; copy number 9: 13; copy number 12: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A8NW-01A-11D-A37B-01): tumor purity 0.62, ploidy 2.23, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 85 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:176,844,493–177,301,253, 1 gene (within-gene range 0–1): AC097518.2.
- chr4:177,181,442–177,362,936, 4 genes: RN7SKP136, AC097518.1, NEIL3, AC027627.1.
- chr5:59,039,761–59,063,503, 1 gene: AC092343.1.
- chr5:59,528,861–59,703,703, 2 genes: NDUFB4P2, MIR582.
- chr13:46,211,940–46,897,076, 20 genes: LRRC63, RN7SKP5, ABITRAMP1, AL139801.1, LINC00563, RUBCNL, RNU2-6P, RNU6-68P, PPP1R2P4, LINC01198, AL138686.2, OR7E101P, AL138686.1, COX17P1, FKBP1AP3, LRCH1, AL359880.1, ESD, HTR2A, HTR2A-AS1.
- chr13:54,311,972–61,176,758, 51 genes (within-gene range 0–1): MIR1297, RPL13AP25, AL442636.1, AL512655.1, AL390964.1, LINC02335, AL139038.1, MIR5007, AL354821.1, HNF4GP1, AL138997.1, SPATA2P1, RN7SKP6, PRR20A, PRR20C, PRR20B, PRR20D, PRR20E, PRR20FP, MTCO2P3, SLC25A5P4, RPL31P53, PCDH17, AL445288.1, RNA5SP30, LINC02338, LINC00374, AL161423.1, RNY4P29, CTAGE16P, DNAJA1P1, HMGN2P39, POLR3KP1, AL159156.1, RPP40P2, RNU7-88P, DIAPH3, DIAPH3-AS1, RN7SL375P, DIAPH3-AS2, RNY4P28, LINC00434, TARDBPP2, AL359920.1, TDRD3, RNA5SP31, LINC00378, EIF4A1P6, AL161901.1, RNY3P5, LINC01442.
- chr19:21,932,958–22,010,949, 1 gene (within-gene range 0–2): ZNF208.
- chr19:21,965,708–22,091,480, 5 genes: AC003973.2, BNIP3P28, AC003973.1, ZNF257, BNIP3P29.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,857 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:237,042,184–240,475,187, 40 genes, copy number 5 (within-gene range 2–5): RYR2, RN7SKP195, MIR4428, AL442065.1, AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1.
- chr5:21,616,262–45,895,970, 343 genes, copy number 5–6 (broad region; genes not listed).
- chr7:109,322,320–109,960,184, 5 genes, copy number 6: AC002386.1, AC073071.1, AC073387.1, AC073387.2, EIF3IP1.
- chr9:34,049,966–35,732,195, 88 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr11:24,455,911–30,368,646, 62 genes, copy number 6–12 (broad region; genes not listed).
- chr11:30,830,369–36,675,695, 112 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr11:39,024,631–48,228,310, 172 genes, copy number 5–6 (within-gene range 1–6) (broad region; genes not listed).
- chr11:49,405,091–57,701,182, 200 genes, copy number 5–9 (within-gene range 2–9) (broad region; genes not listed).
- chr11:57,917,297–59,058,659, 52 genes, copy number 7 (within-gene range 2–7): OR5AZ1P, OR5BD1P, CYCSP26, OR9Q1, RNU6-899P, OR6Q1, VN2R9P, AP004247.2, AP004247.1, OR9L1P, OR9I3P, OR9I1, OR9I2P, OR5BL1P, OR9Q2, OR1S2, OR1S1, OR10Q1, EIF4A2P3, OR10W1, OR10Q2P, OR5BC1P, OR5B19P, OR5B10P, AP000435.1, OR5B17, OR5B1P, OR5B15P, OR5B3, OR5B2, OR5B12, AP003557.2, AP003557.1, OR5B21, LPXN, ZFP91, ZFP91-CNTF, AP001350.1, CNTF, AP001350.2, GLYAT, AP000445.1, AP000445.2, TMA16P1, GLYATL2, GLYATL1P2, GLYATL1, AP001652.1, AP001636.3, AP001636.2, GLYATL1P1, AP001636.1.
- chr11:67,252,336–71,252,577, 139 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr13:89,181,324–89,837,237, 9 genes, copy number 5: LINC00440, LINC01047, TRIM60P13, SP3P, LINC02336, LINC01040, LINC00353, RPL7L1P1, AL355821.1.
- chr15:19,878,555–26,455,217, 298 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr15:36,341,739–36,572,212, 3 genes, copy number 7: AC087516.1, AC087516.2, COX6CP4.
- chr15:36,613,474–36,669,097, 4 genes, copy number 7 (within-gene range 2–7): AC103988.1, LARP4P, TPST2P1, AC013640.1.
- chr19:30,553,956–34,355,566, 78 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr19:37,497,159–58,605,223, 1,358 genes, copy number 5 (broad region; genes not listed).
- chr20:30,323,367–64,313,132, 894 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,256. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
